Somatic mutation profile of tumor specimen TCGA-EL-A3CU-01A (aliquot TCGA-EL-A3CU-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 70.9 years (25,881 days).
Specimen TCGA-EL-A3CU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3935db01-4252-4c60-ac7f-a0cc5cc3baa7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CU-10A (Blood Derived Normal), aliquot TCGA-EL-A3CU-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e3e9318-06ce-4be5-8d46-597a33958a6f

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ALG10B | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.265); catalogued as rs1263129774, COSV58144616; called by muse, mutect2
- CHCHD2 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV68170187; called by muse, mutect2, varscan2
- DGKQ | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs773035998, COSV56619930; called by muse, mutect2, varscan2
- EDRF1 | c.80A>T p.Q27L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV61766455; called by muse, mutect2, varscan2
- FGF20 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.304); catalogued as COSV51662414; called by muse, mutect2, varscan2
- FLG2 | c.4952C>A p.S1651Y | Missense Mutation (SNP) | VAF 115/437 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); catalogued as rs188198910; called by muse, mutect2, varscan2
- GPR119 | c.295A>C p.I99L | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV52276713; called by muse, mutect2, varscan2
- MORF4L2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV64611506; called by muse, mutect2, varscan2
- PRDM16 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as COSV54610495; called by muse, mutect2, varscan2
- TTN | c.68948C>T p.T22983I (on ENST00000591111; = p.T15559I on NM_003319.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | PolyPhen probably damaging (0.912); catalogued as COSV60376893; called by muse, mutect2, varscan2
- UGT2A1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV54140051, COSV99684783; called by muse, mutect2, varscan2
- BSN | c.4441_4442del p.S1481Pfs*83 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by pindel, varscan2
- MYH15 | c.5778del p.E1926Dfs*91 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | called by mutect2, pindel, varscan2
- WASHC2A | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, varscan2
- CYB5D1 | c.16C>T p.L6= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV54687676; called by muse, mutect2, varscan2
- MICALL1 | c.672G>A p.G224= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV53243614; called by muse, mutect2
- PPRC1 | c.4515C>T p.S1505= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV53388944; called by muse, mutect2, varscan2
- RGS18 | c.360A>G p.E120= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV66510217; called by muse, mutect2
- PCLAF | c.*26C>T | 3'UTR (SNP) | VAF 12/40 reads (30%) | catalogued as rs770953682, COSV100257056; called by muse, mutect2, varscan2
